Surgical pathology report (de-identified scan), TCGA case TCGA-G7-7502, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Roswell Park, specimen TCGA-G7-7502-01A (Primary Tumor).

[page 1 of 2]
SPECIMENS:

- A. TUMOR BED LEFT PARTIAL NEPHRECTOMY
- B. LEFT PARTIAL NEPHRECTOMY

SPECIMEN(S):

- A. TUMOR BED LEFT PARTIAL NEPHRECTOMY
- B. LEFT PARTIAL NEPHRECTOMY

DIAGNOSIS:

- A. KIDNEY, LEFT, TUMOR BED BIOPSY:
- NEGATIVE FOR MALIGNANCY
- B. KIDNEY, LEFT, PARTIAL NEPHRECTOMY:
- RENAL CELL CARCINOMA, PAPILLARY TYPE
- FUHRMAN NUCLEAR GRADE 2
- TUMOR SIZE: 6.2 X 6 X 5.3 CM
- SURGICAL MARGIN PSITIVE (FOCAL: 1MM)
- NO VASCULAR INVASION IDENTIFIED
- TUMOR LIMITED TO THE KIDNEY

SYNOPTIC REPORT - KIDNEY (PARTIAL OR RADICAL)

Specimens Involved

Specimens: A: TUMOR BED LEFT PARTIAL NEPHRECTOMY

B: LEFT PARTIAL NEPHRECTOMY

Specimen Type: Partial nephrectomy

Without adrenal gland

Laterality: Left

Tumor Site: Not specified

Focality: Unifocal

Tumor Size (largest tumor if multiple): Greatest dimension: 6.2cm

Additional dimensions: 6cm x 5.3cm

Macroscopic Extent of Tumor: Tumor limited to kidney

WHO CLASSIFICATION

Papillary renal cell carcinoma 8260/3

Histologic Grade (Fuhrman Nuclear Grade): G2: Nuclei slightly irregular, approximately 15 u; nucleoli evident

Invasion of Vascular/Lymphatic: Absent

Perinephric Tissue Invasion: Absent

Margins: Margin(s) involved by invasive carcinoma

Include: Renal parenchymal margin (partial nephrectomy only)

Distance: 0cm

Adrenal Gland: Not present

Regional Lymph Nodes: None sampled

Additional Findings: None identified

Pathological Staging (pTNM): pT 1b N X M X

Pathological staging is based on the AJCC Cancer Staging Manual, 7th Edition

pMX: Cannot be assessed

GROSS DESCRIPTION:

A. TUMOR BED LEFT PARTIAL NEPHRECTOMY

Received fresh labeled with the patient's identification and designated "tumor bed, left partial nephrectomy" is a fragment of tan fibrous tissue measuring 0.3 x 0.3 x 0.2 cm. Entirely submitted for frozen section, FSA.

B. LEFT PARTIAL NEPHRECTOMY

Received fresh labeled with the patient's identification and designated "left partial nephrectomy" is an intact, unoriented, partial nephrectomy specimen, 6.5 x 6 x 5.3 cm, with detached fragment of adipose tissue, 13.2 x 4.5 x 2 cm, collectively weighing 104 g. The parenchymal margin inked black, remainder of kidney specimen inked blue. The kidney is sectioned to show an encapsulated, golden tan, lobulated, soft friable mass measuring 6.2 x 6 x 5.3 cm, approaching the parenchymal margin at distance of 0.3

[page 2 of 2]
[REDACTED]

cm. The fragment of adipose tissue is sectioned to show unremarkable cut surface. Gross photographs are taken. A portion of the specimen is submitted for tissue procurement, representatively submitted:
B1-B5: Representative sections, mass and parenchymal margin
B6-B9: Representative sections, mass
B10: Representative sections, detached fragment adipose tissue

CLINICAL HISTORY:

None given

PRE-OPERATIVE DIAGNOSIS:

Left renal mass

FROZEN SECTION INTRAOPERATIVE REPORT:

FSA: Soft tissue, tumor bed, biopsy: Fibroadipose tissue defer to permanent

Diagnosis called at [REDACTED]

Gross Dictation: [REDACTED]

Microscopic/Diagnostic Dictation:., Pathologist, [REDACTED]

Final Review:., Pathologist, [REDACTED]

Final: Pathologist [REDACTED]

Source: NCI Genomic Data Commons file 04f2d9f2-643f-46ac-af5a-7ecb0f475aa5 (TCGA-G7-7502.56AD9F3C-F253-4FF4-A7EF-C89E1F7DB059.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).